CPTAC case C3L-01063 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/780fb6da-c1a4-4131-9385-93cda408c39c

Demographics
Sex at birth: female; Race: white; Year of birth: 1933; Vital status: Dead; Days to death: 285 days; Year of death: 2018; Cause of death: Cardiovascular Disorder, NOS; Country of birth: Russia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 84.4 years (30,810 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T4b; AJCC pathologic N: N3; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 285 days; Progression or recurrence: yes; Days to recurrence: 73 days; Days to last follow up: 0 days; Clark level: III; Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 2.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 8; Lymph nodes tested: 10; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: With Tumor.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01063-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 270 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01063-23: Section location: Extremities; Percent tumor nuclei: 95; Percent necrosis: 0.
- Sample C3L-01063-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 250 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01063-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
